Somatic mutation profile of tumor specimen BA2334D (aliquot aq-BA2334D) from BEATAML1.0 case 2270, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with t(6;9)(p23;q34), DEK-NUP214; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.5 years (11,136 days).
Specimen BA2334D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae117d39-4132-4adc-a853-84668f513f2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2739D (Solid Tissue Normal), aliquot aq-BA2739D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f0f4d27-f2e7-4405-b4d7-605d3af636e1

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, In Frame Ins 2, 5'UTR 1, 5'Flank 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 27/191 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909646, COSV54042199, COSV54043241, COSV54057031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC109583.1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760899643; called by muse, mutect2, varscan2
- ANKFY1 | c.2072C>A p.P691Q (on ENST00000341657 / NM_001330063.2; = p.P692Q on NM_016376.5) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV58920130; called by muse, mutect2, varscan2
- GRIK2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV59725067; called by muse, mutect2, varscan2
- KLHDC8A | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs778433451; called by muse, mutect2, varscan2
- SP140L | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755915629, COSV99707286; called by muse, mutect2, varscan2
- SSC5D | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 95/211 reads (45%) | catalogued as rs1428127033; called by muse, mutect2, varscan2
- THRAP3 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs755546658, COSV63567374; called by muse, mutect2, varscan2
- WASH6P | c.945_946insGCACCACCA p.T315_P316insAPP | In Frame Ins (INS) | VAF 8/66 reads (12%) | catalogued as rs752723594; called by pindel, varscan2
- ANP32B | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EYA3 | c.818_819insGGC p.D273delinsEA | In Frame Ins (INS) | VAF 7/59 reads (12%) | called by pindel, varscan2
- MAMDC4 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PCDHGA5 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- SCRT2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- PTN | c.-194C>A | 5'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- SNORD114-14 | chr14:100969815 T>C | 5'Flank (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- TPSD1 | chr16:1262491 C>T | 3'Flank (SNP) | VAF 117/264 reads (44%) | catalogued as rs1282796644; called by muse, mutect2, varscan2
